MMRF case MMRF_2472 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f484653f-cad1-4736-a25a-0eb567572de4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.9 years (22,987 days); ISS stage: I; Days to last known disease status: 734 days (2.0 years); Days to last follow up: 734 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 36 days; Days to treatment end: 283 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 283 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.615 mg/dL; Immunoglobulin G 7.26 g/L; Immunoglobulin A 11.1 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.58 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 5.17 mmol/L; C-Reactive Protein 0.33 mg/dL.
- Day 91 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.966 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.795 mg/dL; Immunoglobulin G 7.06 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.39 mmol/L.
- Day 190 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.657 mg/dL; Immunoglobulin G 7.01 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 302 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 4.79 mmol/L.
- Day 218 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.556 mg/dL; Immunoglobulin G 7.63 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.11 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 5.39 mmol/L.
- Day 316 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.991 mg/dL; Immunoglobulin G 8.69 g/L; Immunoglobulin A 0.94 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 386: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 9.25 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.17 mmol/L.
- Day 479 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.911 mg/dL; Immunoglobulin G 8.97 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 588 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.992 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.63 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 5.56 mmol/L.
- Day 734 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -4: Weight: 73 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2472_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2472_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
